Somatic mutation profile of tumor specimen C3L-08266-04 (aliquot CPT0477750008) from CPTAC case C3L-08266, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 70.9 years (25,910 days).
Specimen C3L-08266-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82e4f2f5-2dd2-4d43-8c63-99200d5cbeff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08266-31 (Blood Derived Normal), aliquot CPT0475700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25e09e7f-e166-42b3-89fb-6e822f4b937e

The open-access MAF lists 138 somatic variants for this specimen: 107 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 28, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 1, In Frame Del 1, Splice Region 1, 3'UTR 1, Nonstop Mutation 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 89/780 reads (11%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- MED12 | c.3443G>A p.R1148H | Missense Mutation (SNP) | VAF 87/367 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.695); catalogued as rs387907360, CM138035, COSV100375721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARMC4 | c.2688A>C p.E896D | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV59470786; called by muse, mutect2, varscan2
- ASXL3 | c.3565A>C p.S1189R | Missense Mutation (SNP) | VAF 80/778 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV99036122; called by muse, mutect2
- ATP10A | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 81/646 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs776815675, COSV100791706, COSV63517157; called by muse, mutect2, varscan2
- BOD1L1 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 35/446 reads (8%) | catalogued as COSV50090994; called by muse, mutect2
- C11orf87 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 81/846 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59357518; called by muse, mutect2
- CAD | c.2759C>T p.T920M | Missense Mutation (SNP) | VAF 71/872 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201694266, COSV53030573; called by muse, mutect2
- CAMSAP1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 123/1157 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as rs140696174; called by muse, mutect2, varscan2
- CCDC124 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 92/771 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71490493; called by muse, mutect2, varscan2
- CCDC141 | c.4237A>G p.R1413G | Missense Mutation (SNP) | VAF 46/640 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1250111685; called by muse, mutect2
- CCDC168 | c.3228del p.K1076Nfs*14 | Frame Shift Del (DEL) | VAF 44/235 reads (19%) | catalogued as rs765903699; called by mutect2, varscan2
- CD3E | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 37/388 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs143630318; ClinVar: uncertain significance; called by muse, mutect2
- CHST4 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 105/929 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs766375058; called by muse, mutect2, varscan2
- COL7A1 | c.7097G>T p.G2366V | Missense Mutation (SNP) | VAF 79/737 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040989, CM103727, CM111642; called by muse, mutect2, varscan2
- DGKI | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 77/633 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1018542228, COSV55974162; called by muse, mutect2, varscan2
- DMD | c.8450T>G p.L2817R | Missense Mutation (SNP) | VAF 112/460 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58914465; called by muse, mutect2, varscan2
- EPHA3 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 78/892 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV60709807; called by muse, mutect2
- FBXW4 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 72/505 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774279870; called by muse, mutect2, varscan2
- FZD5 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 86/1026 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs867776061; called by muse, mutect2
- GABRG1 | c.888A>C p.K296N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99778418; called by muse, mutect2
- GOLGB1 | c.5854G>T p.E1952* | Nonsense Mutation (SNP) | VAF 27/225 reads (12%) | catalogued as COSV61472957; called by muse, mutect2, varscan2
- GUCA1A | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 72/790 reads (9%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs749286416, COSV50003745; called by muse, mutect2
- ITGAV | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 135/705 reads (19%) | catalogued as rs1375551580, COSV53711956; called by muse, mutect2, varscan2
- KCNH5 | c.85T>G p.L29V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.162); catalogued as COSV59763416; called by muse, mutect2
- KCNQ3 | c.1698G>A p.T566= | Splice Region (SNP) | VAF 50/526 reads (10%) | catalogued as rs781066375, COSV66471518; called by muse, mutect2
- KIAA1109 | c.14020C>T p.R4674C | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278017597, COSV52663636; called by muse, mutect2, varscan2
- LCE2A | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 292/1119 reads (26%) | catalogued as rs200493380, COSV64227018; called by muse, mutect2, varscan2
- LHFPL6 | c.417C>A p.Y139* | Nonsense Mutation (SNP) | VAF 86/862 reads (10%) | catalogued as COSV65445036; called by muse, mutect2
- LHX9 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 291/1019 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436058, COSV61328079; called by muse, mutect2, varscan2
- LRP2 | c.8101G>T p.G2701C | Missense Mutation (SNP) | VAF 82/935 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV99786249; called by muse, mutect2
- MEIS3 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 63/574 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.269); catalogued as rs753667318; called by muse, mutect2, varscan2
- MYH7B | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 81/1029 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs746702906, COSV53419453; called by muse, mutect2
- MYO19 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 118/1046 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs749106809; called by muse, mutect2, varscan2
- NYAP2 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 86/896 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284321948; called by muse, mutect2, varscan2
- OR8D1 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 89/955 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV63442235; called by muse, mutect2
- PCDH17 | c.2394C>G p.F798L | Missense Mutation (SNP) | VAF 110/1150 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV64971619; called by muse, mutect2
- PKD1L1 | c.7972G>T p.A2658S | Missense Mutation (SNP) | VAF 93/734 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.378); catalogued as rs201946817; called by muse, mutect2, varscan2
- PREX2 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 83/639 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV55750907; called by muse, mutect2, varscan2
- PSG2 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 76/1094 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV68885031; called by muse, mutect2
- PTPRR | c.1699C>T p.L567F | Missense Mutation (SNP) | VAF 80/941 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs781231041; called by muse, mutect2
- RCOR2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 58/486 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs562202011, COSV56850165; called by muse, mutect2, varscan2
- RHOA | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 43/429 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV69042035, COSV69043179; called by muse, mutect2, varscan2
- RIMKLB | c.1161A>G p.*387Wext*4 | Nonstop Mutation (SNP) | VAF 45/396 reads (11%) | catalogued as COSV55235470, COSV55235862; called by muse, mutect2, varscan2
- SDC2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 78/833 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774751152, COSV56226875; called by muse, mutect2
- SEMA3D | c.2307T>G p.D769E | Missense Mutation (SNP) | VAF 54/517 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1394831240; called by muse, mutect2, varscan2
- SLC16A5 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 122/965 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.951); catalogued as rs748499376; called by muse, mutect2, varscan2
- SPTLC3 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 90/941 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370915107; called by muse, mutect2
- STIMATE | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 46/586 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs760255234, COSV100753756, COSV61890708; called by muse, mutect2
- SUSD4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 116/1136 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs775842573; called by muse, mutect2
- TAL1 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 75/560 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs751709263; called by mutect2, varscan2
- THSD7B | c.3701A>C p.K1234T (on ENST00000272643; = p.K1232T on NM_001316349.2) | Missense Mutation (SNP) | VAF 65/631 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs1360239886, COSV55662801; called by muse, mutect2, varscan2
- TRIM49C | c.889A>T p.N297Y | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV101442261; called by muse, mutect2, varscan2
- TRIM58 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 73/876 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV63569233; called by muse, mutect2
- TRPA1 | c.1389G>C p.Q463H | Missense Mutation (SNP) | VAF 115/616 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.06); catalogued as rs757651736; called by muse, mutect2, varscan2
- USH1G | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 118/930 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs770933979, COSV100140673; called by muse, mutect2, varscan2
- ZNF536 | c.3755A>G p.E1252G | Missense Mutation (SNP) | VAF 134/1090 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV62827518; called by muse, mutect2, varscan2
- ZNF98 | c.1109G>T p.R370I | Missense Mutation (SNP) | VAF 46/586 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.045); catalogued as COSV63334011, COSV63337610; called by muse, mutect2
- ACTG1 | c.481C>A p.H161N | Missense Mutation (SNP) | VAF 78/820 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- ADAM29 | c.1726T>C p.F576L | Missense Mutation (SNP) | VAF 111/869 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ANKZF1 | c.1505G>C p.C502S | Missense Mutation (SNP) | VAF 102/907 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARFGEF2 | c.2943T>A p.D981E | Missense Mutation (SNP) | VAF 79/664 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ARHGEF38 | c.1246del p.Q416Rfs*5 | Frame Shift Del (DEL) | VAF 54/420 reads (13%) | called by mutect2, pindel, varscan2
- C2CD6 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 82/751 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CCDC102B | c.1342A>C p.N448H | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CCL11 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 71/621 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CFAP54 | c.3684A>G p.I1228M | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2
- CFHR3 | c.193A>C p.S65R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CLPTM1L | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 77/743 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPNE5 | c.1279C>A p.Q427K | Missense Mutation (SNP) | VAF 77/680 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ECRG4 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 98/957 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- GLB1L2 | c.1880C>A p.P627H | Missense Mutation (SNP) | VAF 90/687 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- GTF3C3 | c.2260+1_2260+2del p.X754_splice | Splice Site (DEL) | VAF 93/513 reads (18%) | called by mutect2, pindel, varscan2
- H1-5 | c.251_259del p.K84_L87delinsI | In Frame Del (DEL) | VAF 81/874 reads (9%) | called by mutect2, pindel*
- HFM1 | c.2339C>A p.A780E | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.234); called by muse, mutect2
- LIG3 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 54/506 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LILRA2 | c.866A>C p.H289P | Missense Mutation (SNP) | VAF 167/1269 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- LRP12 | c.1823A>C p.N608T | Missense Mutation (SNP) | VAF 92/1014 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- MASP2 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 127/1026 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MCM7 | c.1032A>G p.I344M | Missense Mutation (SNP) | VAF 63/525 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEFV | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 87/853 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MEFV | c.1175A>T p.E392V | Missense Mutation (SNP) | VAF 100/964 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- MRPS5 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 32/409 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- NBEA | c.1316T>G p.L439R | Missense Mutation (SNP) | VAF 54/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NOTCH4 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 92/773 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OR2AJ1 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 64/451 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR2T2 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 82/1257 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.147); called by muse, mutect2
- OTOGL | c.2864A>C p.H955P (on ENST00000547103; = p.H946P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCMTD1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PKD1L1 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 100/730 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, varscan2
- PLPPR4 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2
- PTCH1 | c.3246del p.V1083Wfs*4 | Frame Shift Del (DEL) | VAF 110/899 reads (12%) | called by mutect2, pindel, varscan2
- RAPGEF1 | c.1425G>T p.R475S | Missense Mutation (SNP) | VAF 121/962 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RWDD3 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCLT1 | c.1556A>C p.E519A | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCN10A | c.5249A>C p.K1750T | Missense Mutation (SNP) | VAF 96/829 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- SMG1 | c.5240C>A p.S1747Y | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SPTAN1 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 81/677 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SYT4 | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TBL1X | c.951A>C p.E317D | Missense Mutation (SNP) | VAF 81/404 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TEX13C | c.1601A>G p.Q534R | Missense Mutation (SNP) | VAF 130/710 reads (18%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- TMEM259 | c.1224C>G p.F408L | Missense Mutation (SNP) | VAF 53/565 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNRC6A | c.1913C>A p.T638K | Missense Mutation (SNP) | VAF 85/705 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- TTN | c.56152A>C p.S18718R (on ENST00000591111; = p.S11294R on NM_003319.4) | Missense Mutation (SNP) | VAF 74/659 reads (11%) | PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- UNC5D | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 90/751 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- VSTM4 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 93/867 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF658 | c.2556A>C p.K852N | Missense Mutation (SNP) | VAF 86/717 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ALX3 | c.123G>A p.A41= | Silent (SNP) | VAF 114/1077 reads (11%) | called by muse, mutect2
- CBWD5 | c.24G>C p.V8= | Silent (SNP) | VAF 65/611 reads (11%) | called by muse, mutect2, varscan2
- CDC42BPG | c.1107C>T p.D369= | Silent (SNP) | VAF 46/519 reads (9%) | catalogued as rs769740945, COSV100712122; called by muse, mutect2
- CDH26 | c.1320C>T p.S440= | Silent (SNP) | VAF 78/796 reads (10%) | catalogued as rs747859766; called by muse, mutect2, varscan2
- CHAT | c.867G>A p.T289= | Silent (SNP) | VAF 107/785 reads (14%) | catalogued as rs574542737, COSV60319512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP3 | c.2220C>T p.R740= | Silent (SNP) | VAF 84/682 reads (12%) | catalogued as rs542950831; called by muse, mutect2, varscan2
- F2R | c.1143C>T p.Y381= | Silent (SNP) | VAF 107/710 reads (15%) | catalogued as rs757455751; called by muse, mutect2, varscan2
- FPR2 | c.45G>C p.V15= | Silent (SNP) | VAF 61/599 reads (10%) | called by muse, mutect2, varscan2
- KDR | c.3813T>G p.T1271= | Silent (SNP) | VAF 22/210 reads (10%) | called by mutect2, varscan2
- KREMEN2 | c.1212G>A p.P404= (on ENST00000303746 / NM_172229.3; = p.R378Q on NM_024507.4) | Silent (SNP) | VAF 69/834 reads (8%) | catalogued as rs775520120, COSV51893060; called by muse, mutect2
- LOXHD1 | c.4662C>T p.D1554= | Silent (SNP) | VAF 88/862 reads (10%) | catalogued as rs771306615, COSV56072539; called by muse, mutect2, varscan2
- MESP2 | c.807G>A p.A269= | Silent (SNP) | VAF 94/1158 reads (8%) | catalogued as rs755019731; called by muse, mutect2
- NRXN2 | c.4770G>A p.P1590= | Silent (SNP) | VAF 126/1012 reads (12%) | catalogued as rs753250263; called by muse, mutect2, varscan2
- NSUN4 | c.546A>G p.A182= | Silent (SNP) | VAF 88/765 reads (12%) | catalogued as rs138408069; called by muse, mutect2, varscan2
- P3H3 | c.1392G>A p.S464= | Silent (SNP) | VAF 57/587 reads (10%) | catalogued as rs781929251, COSV51836639; called by muse, mutect2, varscan2
- PCDHB1 | c.813G>A p.E271= | Silent (SNP) | VAF 99/852 reads (12%) | catalogued as COSV100128059; called by muse, mutect2, varscan2
- PIEZO2 | c.486A>G p.E162= | Silent (SNP) | VAF 36/332 reads (11%) | called by mutect2, varscan2
- POLR2B | c.1284T>C p.D428= | Silent (SNP) | VAF 40/448 reads (9%) | catalogued as rs774060806; called by muse, mutect2
- PUM3 | c.1632A>G p.G544= | Silent (SNP) | VAF 58/440 reads (13%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.1051A>C p.R351= | Silent (SNP) | VAF 39/356 reads (11%) | called by muse, mutect2, varscan2
- RP1 | c.610A>C p.R204= | Silent (SNP) | VAF 45/476 reads (9%) | called by muse, mutect2
- RP1 | c.6273C>A p.I2091= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV99078565; called by muse, mutect2
- SEC31A | c.723C>T p.I241= | Silent (SNP) | VAF 86/732 reads (12%) | called by muse, mutect2, varscan2
- SH2B2 | c.456G>A p.A152= | Silent (SNP) | VAF 94/1025 reads (9%) | called by muse, mutect2
- TLR3 | c.1461C>T p.L487= | Silent (SNP) | VAF 76/690 reads (11%) | catalogued as rs767185774; called by muse, mutect2, varscan2
- VCAN | c.2895T>G p.T965= | Silent (SNP) | VAF 49/454 reads (11%) | catalogued as rs141161041; called by muse, mutect2, varscan2
- WDR7 | c.2652T>A p.R884= | Silent (SNP) | VAF 76/800 reads (10%) | called by muse, mutect2
- ZNF649 | c.321C>T p.H107= | Silent (SNP) | VAF 79/805 reads (10%) | catalogued as rs200012694; called by muse, mutect2
- AL353804.7 | chrX:73851824 G>A | 3'Flank (SNP) | VAF 65/336 reads (19%) | called by muse, mutect2, varscan2
- CCDC70 | c.-22G>A | 5'UTR (SNP) | VAF 34/574 reads (6%) | catalogued as rs369776694; called by muse, mutect2
- ITGB1 | c.*1G>A | 3'UTR (SNP) | VAF 30/304 reads (10%) | catalogued as rs755421136; called by muse, mutect2, varscan2
